Gene-level copy-number profile of tumor specimen TCGA-D3-A1Q3-06A from TCGA case TCGA-D3-A1Q3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.3 years (23,852 days).
Specimen TCGA-D3-A1Q3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.26ea271b-53cc-44b2-9373-c5eab0390366.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A1Q3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bc8a679d-6130-4df8-8feb-e5437afffca2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,088; copy number 2: 41,938; copy number 3: 11,116; copy number 4: 2,800; copy number 5: 47; copy number 6: 119; copy number 7: 97; copy number 8: 41; copy number 9: 158; copy number 10: 119; copy number 11: 30; copy number 13: 12; copy number 14: 13; copy number 15: 52; copy number 16: 36; copy number 17: 12; copy number 18: 2; copy number 20: 21; copy number 26: 52; copy number 27: 7; copy number 28: 27; copy number 32: 5; copy number 33: 7; copy number 40: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A1Q3-06A-11D-A194-01): tumor purity 0.63, ploidy 2.33, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 873 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–59,075,256, 133 genes, copy number 8–17 (broad region; genes not listed).
- chr5:58,198–438,291, 14 genes, copy number 9 (within-gene range 2–12): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR.
- chr5:850,291–1,295,068, 15 genes, copy number 10: BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:1,725,149–1,728,172, 1 gene, copy number 10: AC112176.1.
- chr5:6,019,029–6,600,288, 10 genes, copy number 13–27 (within-gene range 2–27): AC010266.2, AC010266.1, AC026797.1, HMGB3P3, LINC02145, MED10, AC093307.1, UBE2QL1, AC027334.1, LINC01018.
- chr5:8,614,356–9,903,852, 27 genes, copy number 28: AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221.
- chr5:10,564,070–13,190,677, 18 genes, copy number 5–18 (within-gene range 5–43): ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P, RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1.
- chr5:14,143,342–14,532,128, 1 gene, copy number 11 (within-gene range 4–20): TRIO.
- chr5:14,581,792–15,266,541, 17 genes, copy number 11 (within-gene range 4–11): OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, AC016575.2, U8, LINC02149.
- chr5:19,471,296–27,496,994, 74 genes, copy number 5–40 (within-gene range 3–40) (broad region; genes not listed).
- chr5:28,548,135–41,510,628, 209 genes, copy number 6–33 (broad region; genes not listed).
- chr5:42,188,266–42,191,523, 1 gene, copy number 7: AC108099.1.
- chr5:42,729,138–42,924,535, 5 genes, copy number 17 (within-gene range 3–17): AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2.
- chr5:45,035,199–45,895,970, 6 genes, copy number 8–32: AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr5:143,531,331–143,828,772, 6 genes, copy number 5 (within-gene range 3–5): AC016598.2, RNU7-156P, AC008696.2, MIR5197, AC008696.1, HMHB1.
- chr5:148,923,639–149,944,793, 33 genes, copy number 6 (within-gene range 2–6): SH3TC2, AC116312.1, RNU6-732P, MIR584, SH3TC2-DT, RN7SKP145, ABLIM3, AC012613.1, AC012613.2, AFAP1L1, AC131025.3, GRPEL2, GRPEL2-AS1, PCYOX1L, IL17B, AC131025.1, CARMN, AC131025.2, MIR143, MIR145, CSNK1A1, AC021078.1, RPL29P14, ARHGEF37, RNU6-588P, AC022100.1, U3, RN7SL868P, PPARGC1B, MIR378A, PDE6A, MFFP2, Y_RNA.
- chr5:151,822,513–151,924,851, 1 gene, copy number 13 (within-gene range 4–13): GLRA1.
- chr5:151,875,566–153,223,543, 6 genes, copy number 13: RNA5SP198, LINC01933, AC008571.2, NMUR2, AC008571.1, LINC01470.
- chr5:174,336,295–174,633,209, 5 genes, copy number 6 (within-gene range 4–6): LINC01411, GAPDHP71, SUMO2P6, AC108112.1, HIGD1AP3.
- chr5:175,906,939–178,086,529, 87 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr5:178,690,804–180,292,099, 63 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr22:19,479,457–19,724,772, 9 genes, copy number 15: CDC45, AC000082.1, CLDN5, LINC00895, AC000077.1, AC000067.1, SEPTIN5, AC000093.1, GP1BB.
- chr22:20,350,578–21,517,533, 71 genes, copy number 15–26 (within-gene range 3–26) (broad region; genes not listed).
- chr22:25,742,144–26,031,045, 6 genes, copy number 11: MYO18B, AL022329.3, MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1.
- chr22:26,443,423–26,514,568, 4 genes, copy number 10: HPS4, SRRD, TFIP11, Z95115.1.
- chr22:38,111,495–38,214,778, 1 gene, copy number 15 (within-gene range 3–15): PLA2G6.
- chr22:38,200,767–38,685,421, 23 genes, copy number 15: MAFF, TMEM184B, AL020993.1, RN7SL704P, Metazoa_SRP, CSNK1E, TPTEP2-CSNK1E, TPTEP2, Z98749.1, Z97056.2, Z97056.1, KCNJ4, Z97056.3, KDELR3, DDX17, DMC1, RPS29P31, FAM227A, CBY1, AL021707.4, AL021707.2, AL021707.9, TOMM22.
- chr22:44,139,365–44,652,379, 15 genes, copy number 9–14: AL031595.3, PARVG, AL031595.1, AL031595.2, SHISAL1, Z85994.1, Z85994.2, LINC01656, MRPS18CP6, AL023973.1, RTL6, KRT18P23, LINC00207, LINC00229, ANP32BP2.
- chr22:48,274,364–48,451,217, 4 genes, copy number 7–13: MIR3201, AL008720.2, Z72006.1, Z82249.1.
- chr22:50,674,415–50,801,309, 8 genes, copy number 5 (within-gene range 2–5): SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 707. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
